Somatic mutation profile of tumor specimen 0DAEHP from CCDI case PBBJZE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.9 years (2,887 days).
Specimen 0DAEHP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3458cecc-4f0d-476a-89f9-c4cad2e0ae19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAEHD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ae023b5-5f4e-44fb-a020-cabbeffeed78

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Splice Region 1, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1460G>A p.R487H (on ENST00000399959; = p.R488H on NM_001356.5) | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs796052235, CM158043, COSV67864331; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 67/405 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 41/675 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462184772, COSV100875681; called by muse, mutect2
- ARAP2 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.265); catalogued as COSV58285115; called by muse, mutect2, varscan2
- CORIN | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 31/461 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774240507, COSV56693176, COSV56695937; called by muse, mutect2
- DDX3X | c.826G>C p.E276Q (on ENST00000399959; = p.E277Q on NM_001356.5) | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864271; called by muse, mutect2, varscan2
- FAM83B | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs868155358, COSV60924635; called by muse, mutect2, varscan2
- NCOA7 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 88/890 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1232071252, COSV99997205; called by muse, mutect2
- NYNRIN | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 167/427 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs762063546; called by muse, mutect2, varscan2
- SORCS2 | c.3029G>A p.G1010E | Missense Mutation (SNP) | VAF 51/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs760207977, COSV61173129; called by muse, mutect2, varscan2
- SRM | c.765G>A p.P255= | Splice Region (SNP) | VAF 18/456 reads (4%) | catalogued as rs1271034972; called by muse, mutect2
- ELF4 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- FBL | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 59/434 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUP214 | c.4468G>T p.G1490C | Missense Mutation (SNP) | VAF 149/518 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- PDE4DIP | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 15/712 reads (2%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2
- PTPRO | c.3217C>A p.Q1073K (on ENST00000281171 / NM_030667.3; = p.Q1045K on NM_002848.4) | Missense Mutation (SNP) | VAF 55/415 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2481G>T p.K827N | Missense Mutation (SNP) | VAF 65/809 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- SHROOM1 | c.1408A>C p.T470P | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- TSGA10 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 67/582 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by mutect2, varscan2
- UBE2A | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 124/188 reads (66%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by mutect2, varscan2
- APOE | c.351G>A p.A117= | Silent (SNP) | VAF 33/280 reads (12%) | catalogued as COSV52985037; called by muse, mutect2, varscan2
- GCC2 | c.3441G>A p.L1147= | Silent (SNP) | VAF 55/452 reads (12%) | called by muse, mutect2, varscan2
- GPLD1 | c.2265C>T p.D755= | Silent (SNP) | VAF 88/338 reads (26%) | catalogued as rs1062519; called by muse, mutect2
- RBM33 | c.75C>T p.G25= | Silent (SNP) | VAF 38/673 reads (6%) | catalogued as rs751255561, COSV55298785; called by muse, mutect2
- TYR | c.312G>A p.K104= | Silent (SNP) | VAF 21/223 reads (9%) | called by muse, mutect2
- BHMT2 | c.*75C>T | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- LARP4B | c.1531-59G>A | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- SPATA31C1 | n.3736C>T | RNA (SNP) | VAF 40/164 reads (24%) | catalogued as rs553309889; called by muse, mutect2, varscan2
